Gene-level copy-number profile of tumor specimen TCGA-EA-A3HR-01A from TCGA case TCGA-EA-A3HR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage II; Tumor grade: G2; Age at diagnosis: 57.4 years (20,980 days).
Specimen TCGA-EA-A3HR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.107a24e7-043e-4dcb-a0e5-8a05b9977535.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EA-A3HR-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f5c7ca6f-b869-4654-a022-d96f589e25d8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 88; copy number 2: 8,622; copy number 3: 1,549; copy number 4: 35,884; copy number 5: 8,236; copy number 6: 2,372; copy number 7: 1,244; copy number 8: 136; copy number 9: 441; copy number 10: 600; copy number 11: 360; copy number 12: 46; copy number 15: 58; copy number 16: 163; copy number 19: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EA-A3HR-01A-11D-A20T-01): tumor purity 0.75, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,898,423–140,992,659, 2 genes: LRRC57P1, Y_RNA.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,673 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:100,609,601–101,522,979, 15 genes, copy number 19: ADGRG7, AC069223.1, GMFBP1, TFG, ABI3BP, AC080014.1, RNU6-865P, ACTR3P3, IMPG2, SENP7, ZNF90P1, AC110994.1, AC110994.2, Y_RNA, FAM172BP.
- chr3:168,008,689–198,222,513, 600 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 9–11 (broad region; genes not listed).
- chr19:37,823,722–40,898,282, 163 genes, copy number 16 (within-gene range 2–16) (broad region; genes not listed).
- chr19:43,996,896–44,993,341, 58 genes, copy number 15: AC006213.1, ZNF230, AC067968.2, ZNF222, AC067968.1, ZNF223, ZNF284, RNU6-902P, ZNF224, AC021092.1, ZNF225, ZNF234, AC138470.2, ZNF226, ZNF227, ZNF235, AC138470.1, ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1.
- chr22:42,074,248–46,330,810, 127 genes, copy number 9–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 88. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
